MMRF case MMRF_2222 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/271eac13-c1c0-4708-bfff-7a86ac3261d8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 46.2 years (16,880 days); ISS stage: I; Days to last known disease status: 832 days (2.3 years); Days to last follow up: 832 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 153 days; Days to treatment end: 153 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 154 days; Days to treatment end: 154 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 258 days; Days to treatment end: 915 days (2.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 915 days (2.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 832.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 3): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.49 mg/dL; Immunoglobulin G 4.3 g/L; Immunoglobulin A 28.3 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 9.11 mmol/L; Leukocytes 11 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 8.6 g/dL; Glucose 5.01 mmol/L.
- Day 85 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 5.02 g/L; Immunoglobulin A 2.27 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 12.4 ×10⁹/L; Absolute Neutrophil 10.9 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.08 mmol/L; Albumin 31 g/L; Total Protein 6.3 g/dL; Glucose 5.72 mmol/L.
- Day 191 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 4.73 g/L; Immunoglobulin A 1.71 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.05 mmol/L; Albumin 32 g/L; Total Protein 6.2 g/dL; Glucose 7.32 mmol/L.
- Day 258 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 7.29 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.9 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 6.9 g/dL; Glucose 6.27 mmol/L.
- Day 355: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 8.43 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.44 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 1.93 mmol/L; Albumin 32 g/L; Total Protein 6.2 g/dL; Glucose 5.17 mmol/L.
- Day 411 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 8.77 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 6.1 g/dL; Glucose 5.34 mmol/L.
- Day 495: M Protein 0 g/dL; Immunoglobulin G 8.96 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 8 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 4.95 mmol/L.
- Day 575: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Immunoglobulin G 9.04 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 7.2 g/dL; Glucose 5.12 mmol/L.
- Day 663: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.09 mg/dL; Immunoglobulin G 9.68 g/L; Immunoglobulin A 1.68 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 32 g/L; Glucose 6.05 mmol/L.
- Day 831 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.13 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 1.74 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 6.9 g/dL; Glucose 4.9 mmol/L.

Other clinical attributes
- Day 0: Weight: 115 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2222_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2222_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
